Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TZ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TZ-01A (Primary Tumor).

1CD-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9

Breast, left, modified radical mastectomy: Invasive ductal carcinoma, Nottingham grade II, is identified forming multiple (5) masses in the left breast. The largest mass is situated in the upper outer quadrant and measures 3.2 x 2.7 x 2.3 cm (AJCC pT2). Additional nodules are situated inferior and just superior to the main mass and range in size from 0.5 cm to 0.8 cm in diameter. There is approximately 10% component of ductal carcinoma in situ, cribriform type, intermediate nuclear grade. Skin, nipple, and deep margin are free of neoplasm. Multiple (6 of 30) left axillary lymph nodes are positive for metastatic carcinoma, including multiple (2) matted lymph nodes (AJCC pN2).

HER2/neu has been ordered on paraffin embedded tissues.

Source: NCI Genomic Data Commons file 2e1c795c-1dad-42d4-9f52-827628eb6d4c (TCGA-AR-A0TZ.48F86416-8304-479E-B477-7C37A2F951A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).